Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7OZ, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7OZ-01A (Primary Tumor).

[page 1 of 4]
Age: [REDACTED] years Sex: Male

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Clinical Information

year old male with mesothelioma; Radical Pleurectomy, PDT

ICD-O-3
Mesothelioma, epithelioid NOS
9652/3
Site Pleura NOS C38.4
Op 9/24/13

Final Diagnosis

1. PREVIOUS INCISION SITE:

Skin and underlying soft tissue with scar and changes of previous biopsy site.
No tumor seen.

2. CHEST WALL FATTY MASS:

Sections of mature adipose tissue.

3. RIB:

Benign lamellar bone with trilinear bone marrow formation present.
No tumor seen

4. POSTERIOR INTERCOSTAL NODE:

Sections of lymph node, no tumor seen.

5. PHRENIC NODE:

Tissue and sections of lymph node with presence of malignant mesothelioma.

6. PERIPHRENIC TISSUE:

Fibroadipose tissue and nodules of soft tissue with presence of malignant mesothelioma.

7. PERICARDIUM:

Soft tissue with presence of nodules of malignant mesothelioma, some of which may represent lymph nodes replaced by malignant tumor.

8. STATION 9:

Sections of nodules with lymphoid margin showing presence of malignant mesothelioma, favor replacement of lymph node by malignant mesothelioma.

9. STATION 5:

Sections of lymph node, no tumor seen.

10. STATION 6:

Sections of lymph node, no tumor seen.

11. STATION 7:

Name: [REDACTED]

MRN: [REDACTED]

[page 2 of 4]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Sections of lymph node, no tumor seen.

12. RADICAL PLEURECTOMY:

Pleura with presence of malignant mesothelioma

13. STATION 8:

Sections of lymph node, no tumor seen.

The case material was reviewed and the report verified by: MD
(Electronic signature)

Verification Date:

Note

The malignant tumor is consistent with epithelioid mesothelioma.

The calretinin stain stains the epithelial aspect of the lesion. A prominent underlying stromal component is negative for calretinin and is considered a reactive stromal response rather than a sarcomatoid differentiation

Frozen Section Diagnosis

FS1: Incision Site: Skin with biopsy site at scar. No definite tumor present.

Gross Description

The specimen is received in 13 parts in a container labeled with the patient's name and medical record number.

Specimen #1 is received fresh for frozen section and designated "previous incision site" and consists of a 5.1 x 1.0 cm skin ellipse excised to a depth of 2.1 cm. The skin surface displays a linear scar which spans the entire length of the specimen. Representative sections are submitted for frozen section and the frozen section control is submitted in cassette 1A. Additional representative sections are submitted in cassette 1B.

Specimen #2 is received in formalin and designated "chest wall fatty mass" and consists of a 40 gram, 7.1 x 6.1 x 4.0 cm well circumscribed tan yellow nodule. One surface of the specimen is more ragged and slightly flattened, possibly consistent with the resection margin (inked black). The remaining surfaces are covered by glistening soft tissue. Sectioning reveals tan yellow coarsely lobulated cut surfaces. Representative sections are submitted in cassettes 2A through 2C.

Specimen #3 is received in formalin and designated "rib" and consists of three cylindrical portions of firm and trabeculated bone ranging from 5.5 to 6.5 cm in length and averaging 1.8 cm in diameter, grossly consistent with portions of rib. Each

Name: [REDACTED]
MRN: [REDACTED]

[page 3 of 4]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected
Date Received
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

fragment has red brown, rubbery soft tissue attached, grossly consistent with fragments of muscle. No discrete masses or lesions are identified. A representative section is submitted in cassette 3A following decalcification.

Specimen #4 is received in formalin and designated "posterior intercostal node" and consists of multiple tan yellow to tan gray, irregular to nodular fragments of tissue ranging from 0.2 to 0.9 cm in greatest dimension. The specimen is submitted in toto in cassette 4A.

Specimen #5 is received in formalin and designated "phrenic node" and consists of two nodular fragments of tan gray, rubbery tissue measuring 1.5 and 2.0 cm in greatest dimension. The specimen is submitted in toto in cassette 5A.

Specimen #6 is received in formalin and designated "periphrenic tissue" and consists of a 7.5 x 3.5 x 2.0 cm irregular portion of gray purple to tan yellow, coarsely lobulated tissue which displays multiple tan white, indurated nodules ranging from 0.6 to 0.9 cm in greatest dimension. Representative sections are submitted in cassettes 6A and 6B.

Specimen #7 is received in formalin and designated "pericardium" and consists of multiple ragged and irregular fragments of gray purple to tan yellow soft tissue ranging from 1.0 to 8.5 cm in greatest dimension. The specimen displays multiple tan white, indurated nodules which coalesce on the larger fragment, measuring up to 4.5 cm in greatest dimension. Representative sections are submitted in cassette 7A.

Specimen #8 is received in formalin and designated "station 9" and consists of three tan gray, rubbery and irregular to slightly nodular fragments of tissue ranging from 1.2 to 2.8 cm in greatest dimension. The specimen is submitted in toto in cassette 8A.

Specimen #9 is received in formalin and designated "station 5" and consists of two irregular tan gray, nodular tissue fragments measuring 0.3 and 2.5 cm in greatest dimension. The larger fragment is bisected and the specimen is submitted entirely in cassette 9A.

Specimen #10 is received in formalin and designated "station 6" and consists of a 0.9 x 0.5 x 0.3 cm tan gray, nodular tissue fragment which is submitted in toto in cassette 10A.

Specimen #11 is received in formalin and designated "station 7" and consists of two tan gray to tan yellow nodular soft tissue fragments measuring 0.9 and 1.4 cm in greatest dimension. The specimen is submitted in toto in cassette 11A.

Specimen #12 is received in formalin and designated "radical pleurectomy" and consists of a 17.2 x 16.4 x 7.0 cm aggregate of multiple irregular gray purple to tan yellow, ragged soft tissue fragments which display an abundant amount of tan white, indurated nodules ranging from 0.2 to 7.5 cm in greatest dimension. The nodules appear to coalesce in focal areas. Representative sections are submitted in cassettes 12A through 12E.

Specimen #13 is received in formalin and designated "station 8" and consists of a 1.2 cm in greatest dimension tan gray

Name: [REDACTED]
MRN: [REDACTED]

[page 4 of 4]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Accession No: [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

to tan yellow, nodular soft tissue fragment which is submitted in toto in cassette 13A.

Dictated by:

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

Page 4 of 4

Source: NCI Genomic Data Commons file ddfe7e09-897f-46fd-98cb-f956d1bdd3df (TCGA-TS-A7OZ.EB690ABE-CEB6-4840-B2FC-B12CDE60A8C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).